Somatic mutation profile of tumor specimen C3L-02109-03 (aliquot CPT0109010010_1) from CPTAC case C3L-02109, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 79.1 years (28,885 days).
Specimen C3L-02109-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c5340af2-91b0-4e2c-ac1e-4355531f2bff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02109-31 (Blood Derived Normal), aliquot CPT0109040002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/36ddf1ad-367f-447d-b695-f83d29f5beab

The open-access MAF lists 48 somatic variants for this specimen: 34 protein-altering or splice-affecting, 10 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 10, Intron 3, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 68/474 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 166/1127 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSM4 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 105/655 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.325); catalogued as rs370415520; called by muse, mutect2, varscan2
- ANKRD34A | c.1103C>G p.P368R | Missense Mutation (SNP) | VAF 40/177 reads (23%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.931); catalogued as rs781981808; called by muse, mutect2, varscan2
- DNAH5 | c.8828G>A p.R2943H | Missense Mutation (SNP) | VAF 85/534 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs184758570, COSV54203923; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ESPL1 | c.5023C>T p.R1675C | Missense Mutation (SNP) | VAF 60/438 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV57761590; called by muse, mutect2, varscan2
- FRMD4B | c.2960A>G p.Y987C | Missense Mutation (SNP) | VAF 35/241 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.012); catalogued as rs758394679, COSV101273630; called by muse, mutect2, varscan2
- GKAP1 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 32/372 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.212); catalogued as rs767081495, COSV64489524; called by muse, mutect2
- GSDMA | c.956C>G p.P319R | Missense Mutation (SNP) | VAF 54/368 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV56976684; called by muse, mutect2, varscan2
- H3C11 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 65/578 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.323); catalogued as COSV100137683, COSV58899983; called by muse, mutect2, varscan2
- HEPH | c.362G>T p.R121L (on ENST00000343002; = p.R175L on NM_138737.5) | Missense Mutation (SNP) | VAF 28/220 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs376130905, COSV100294341; called by muse, mutect2, varscan2
- KCNH3 | c.1909G>A p.A637T | Missense Mutation (SNP) | VAF 37/213 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs1486180019, COSV57789775; called by muse, varscan2
- MC3R | c.555C>A p.S185R | Missense Mutation (SNP) | VAF 144/1116 reads (13%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as COSV54764929; called by muse, mutect2, varscan2
- MPPED1 | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 54/1416 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV68838347; called by muse, mutect2
- PSG4 | c.1189C>T p.R397C | Missense Mutation (SNP) | VAF 50/482 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs138668740, COSV54937886; called by muse, mutect2, varscan2
- TTC6 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 35/308 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV101606840; called by muse, mutect2, varscan2
- BLNK | c.14A>G p.N5S | Missense Mutation (SNP) | VAF 68/456 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ERMARD | c.1303C>G p.Q435E | Missense Mutation (SNP) | VAF 24/246 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.039); called by muse, mutect2
- FMR1 | c.1858A>G p.S620G | Missense Mutation (SNP) | VAF 84/603 reads (14%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- GALNTL6 | c.110T>C p.V37A | Missense Mutation (SNP) | VAF 75/544 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GORASP2 | c.1039A>T p.M347L | Missense Mutation (SNP) | VAF 69/526 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR63 | c.794T>C p.I265T | Missense Mutation (SNP) | VAF 68/696 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- IL9R | c.730C>T p.Q244* | Nonsense Mutation (SNP) | VAF 90/888 reads (10%) | called by muse, mutect2, varscan2
- MUC16 | c.43274C>T p.T14425I | Missense Mutation (SNP) | VAF 73/429 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- NR5A1 | c.518T>C p.V173A | Missense Mutation (SNP) | VAF 64/463 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- NVL | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 75/300 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POTED | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 37/279 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- PSG4 | c.1246T>A p.W416R | Missense Mutation (SNP) | VAF 54/532 reads (10%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- RGPD4 | c.2148G>T p.R716S | Missense Mutation (SNP) | VAF 33/393 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- STAC2 | c.943C>T p.P315S | Missense Mutation (SNP) | VAF 52/367 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TENT4A | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 57/323 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNFSF14 | c.499T>C p.Y167H | Missense Mutation (SNP) | VAF 41/348 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TWNK | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 117/861 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- WNT2 | c.892T>C p.S298P | Missense Mutation (SNP) | VAF 70/468 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BBS2 | c.1042C>T p.L348= | Silent (SNP) | VAF 149/1021 reads (15%) | catalogued as rs1407743093; called by muse, mutect2, varscan2
- CRYBB3 | c.117C>T p.C39= | Silent (SNP) | VAF 135/1267 reads (11%) | catalogued as rs764774270, COSV53194520; called by muse, mutect2, varscan2
- CTAG2 | c.111G>A p.A37= | Silent (SNP) | VAF 49/599 reads (8%) | catalogued as COSV55996300; called by muse, mutect2, varscan2
- DACT3 | c.906G>A p.A302= | Silent (SNP) | VAF 20/127 reads (16%) | called by muse, mutect2, varscan2
- DPF1 | c.738G>A p.A246= | Silent (SNP) | VAF 26/200 reads (13%) | catalogued as rs148078050; called by muse, mutect2, varscan2
- ENTPD6 | c.1398G>A p.L466= | Silent (SNP) | VAF 28/209 reads (13%) | called by muse, varscan2
- GPR101 | c.93C>A p.G31= | Silent (SNP) | VAF 29/238 reads (12%) | called by muse, mutect2, varscan2
- KL | c.63G>A p.L21= | Silent (SNP) | VAF 13/78 reads (17%) | called by mutect2, varscan2
- RASGEF1C | c.222C>T p.I74= | Silent (SNP) | VAF 108/749 reads (14%) | catalogued as rs1012710199; called by muse, mutect2, varscan2
- TESK2 | c.1662C>G p.A554= | Silent (SNP) | VAF 41/332 reads (12%) | called by muse, mutect2, varscan2
- F10 | c.747+17C>A | Intron (SNP) | VAF 138/621 reads (22%) | called by muse, mutect2, varscan2
- MARCHF8 | c.242+569C>T | Intron (SNP) | VAF 59/468 reads (13%) | catalogued as rs564144489; called by muse, mutect2, varscan2
- MKRN9P | n.690G>A | RNA (SNP) | VAF 55/329 reads (17%) | called by muse, mutect2, varscan2
- ZNF251 | c.277+25C>T | Intron (SNP) | VAF 23/228 reads (10%) | called by muse, mutect2, varscan2
